Gene-level copy-number profile of tumor specimen TCGA-18-5592-01A from TCGA case TCGA-18-5592, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 57.5 years (21,020 days).
Specimen TCGA-18-5592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.237e110a-9937-41e5-a3b7-6194267af9f5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-5592-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/371f47ac-000b-46b9-aa8c-75d611560630

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 24,623; copy number 2: 28,919; copy number 3: 2,487; copy number 4: 3,314; copy number 5: 6; copy number 6: 359; copy number 25: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-18-5592-01A-01D-1631-01): tumor purity 0.85, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 91 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–24,905,735, 91 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 381 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–69,507,622, 372 genes, copy number 6–25 (broad region; genes not listed).
- chr7:69,598,296–71,713,600, 6 genes, copy number 5 (within-gene range 2–5): AUTS2, AC073873.1, GALNT17, MIR3914-1, MIR3914-2, RN7SKP75.
- chr10:85,156,330–85,212,800, 3 genes, copy number 6: AL358787.2, LINC01519, AL358787.1.

Autosomal genes at a single copy (total copy number 1): 22,202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
